Somatic mutation profile of tumor specimen TCGA-ZB-A96F-01A (aliquot TCGA-ZB-A96F-01A-11D-A428-09) from TCGA case TCGA-ZB-A96F, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 39.3 years (14,344 days).
Specimen TCGA-ZB-A96F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc95c53-7a70-4fda-8e52-84648236273f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96F-10A (Blood Derived Normal), aliquot TCGA-ZB-A96F-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bc258cd-61f7-46ca-ada3-8be54b094cec

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.7006C>T p.R2336C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs431825347, COSV66448051; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NPLOC4 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58617411; called by muse, mutect2, varscan2
- OR14I1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100700469; called by muse, mutect2, varscan2
- OTUD4 | c.2248C>A p.Q750K (on ENST00000447906 / NM_001366057.1; = p.Q685K on NM_001102653.1) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV104437419; called by muse, mutect2
- P4HB | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.505); catalogued as COSV58942138; called by muse, mutect2
- SLC38A5 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs782231740; called by muse, mutect2, varscan2
- TONSL | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1401612084; called by muse, mutect2, varscan2
- ARID3B | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CADPS2 | c.3820G>C p.A1274P | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); called by muse, mutect2
- SLC12A3 | c.1772T>A p.I591N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- TACC1 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TBX3 | c.2053G>A p.A685T (on ENST00000257566 / NM_016569.4; = p.A665T on NM_005996.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.23); called by muse, mutect2
- TMEM102 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2
- ACTN3 | c.2295C>T p.F765= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- MAST4 | c.3808C>T p.L1270= (on ENST00000403625 / NM_001164664.2; = p.L1081= on NM_015183.3) | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- RIMBP2 | c.396C>T p.S132= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs773151382, COSV55476405; called by muse, mutect2, varscan2
- SPTBN4 | c.3774C>G p.A1258= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV58957506; called by muse, mutect2, varscan2
